Somatic mutation profile of tumor specimen 0DNNPZ from CCDI case PBCBPL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.9 years (1,805 days).
Specimen 0DNNPZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 965b2c85-f393-4523-9123-4db6544aac41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNNPS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b038f813-880a-4fcc-bc9e-87308a5b584e

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC12 | c.1132C>T p.R378C (on ENST00000379442; = p.R235C on NM_001164462.1) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as rs186273734, COSV65202810; called by muse, varscan2
- TNNI2 | c.232_234del p.E78del | In Frame Del (DEL) | VAF 125/384 reads (33%) | catalogued as rs757565524; called by pindel, varscan2
- ASB3 | c.121A>G p.N41D | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- VSTM1 | c.-52C>T | 5'UTR (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
